Surgical pathology report (de-identified scan), TCGA case TCGA-CR-6493, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-6493-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED] Final Report

DIAGNOSIS:

- 1) LYMPH NODE, LEVEL 2-4, NECK DISSECTION: 2 OUT OF 13 LYMPH NODES INVOLVED BY SQUAMOUS CELL CARCINOMA (2/13).
- 2) TONGUE, RIGHT, EXCISION: MODERATELY-DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 6.1 CM IN GREATEST DIMENSION, LESS THAN 1 MM FROM MEDIAL MARGIN IN THIS SPECIMEN.
- 3) LYMPH NODE, RIGHT NECK, LEVEL 1, EXCISION: 3 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/3); BENIGN SALIVARY GLAND TISSUE.
- 4) TONGUE, BASE LESION, EXCISION: SQUAMOUS MUCOSA AND SKELETAL MUSCLE, NEGATIVE FOR MALIGNANCY.
- 5) TEETH, REMOVAL: 15 INTACT TEETH, GROSS ONLY (SEE GROSS DESCRIPTION).

COMMENT: These findings correspond to AJCC [REDACTED] edition pathologic stage IVA (pT3; pN2b; pM n/a)

Upper Aerodigestive Tract-including Minor Salivary Glands, Lip, Oral cavity, Nasal Cavity, Paranasal Sinuses, Oropharynx, Nasopharynx, and Hypopharynx
Summary of Findings:

Specimen Type: hemiglossectomy

Tumor Site: tongue

Tumor Size: 6.1 cm in greatest dimension:

Laterality: right

Margins: Margins uninvolved by invasive carcinoma; less than 1 mm from medial margin

Histologic Type: squamous cell carcinoma

Histologic Grade: moderately differentiated

Pathologic Staging (pTMN)

[page 2 of 3]
Primary tumor (pT): pT3
Regional Lymph Nodes (pN): pN2b
Number examined: 15
Numbered involved: 2
Extracapsular extension: no

Perineural invasion: Yes, focal

Lymph-Vascular invasion: not identified

HPV testing ordered: No

Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Malignant neoplasm of tongue

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) right neck dissection levels 2-4, 2)
right tongue-stitch anterior, 3) right
neck level 1, 4) tongue base lesion, 5)
teeth for gross only

GROSS DESCRIPTION:

1) SOURCE: Right Neck Dissection Levels 2-4

The specimen is received fresh in a container labeled with the patient's name, medical record number and "right neck dissection level 2-4." The specimen consists of fibroadipose tissue and lymph nodes measuring in aggregate 6.5 x 7.0 x 1.7 cm. A thorough lymph node dissection was performed and multiple candidate lymph nodes were identified. The largest lymph node appears to be matted to another lymph node and this matted aggregate measures 4.7 x 1.5 x 2.0 cm. The remaining candidate lymph nodes range in size from 1.0 cm to 2.2 cm in greatest dimension. The lymph nodes are bisected and submitted in entirety.

Summary of sections: 1A-1B, largest lymph node bisected, 1/1 each; 1C, 3 candidate lymph nodes, 3/1; 1D, 3 candidate lymph nodes, 3/1; 1E, 5 candidate lymph nodes, 5/1.

2) SOURCE: Right Tongue

Received fresh in a container labeled with the patient's name and MR name and "right tongue-stitch anterior". The specimen consists of a hemiglossectomy specimen measuring 8.9 x 5.0 x 4.8 cm in greatest dimension. The lateral surface shows exposed ulcerated tumor measuring 6.1 x 2.9 cm. This section of the tumor abuts the mucosal surface. The surface of the tongue has two nodular-like lesions present midway moving towards the posterior surface. These nodules are white and hard with petechial

[page 3 of 3]
markings. These two nodules measure 1.2 x 1.0 x 0.3 cm and 0.8 x 0.5 x 0.2 cm. A stitch is present marking the anterior surface of the tongue and was placed by the surgeon. The medial margin is inked black, the posterior margin inked blue and the inferior margin is inked orange. The medial surface shows muscle and no obvious tumor. Both the posterior and the inferior surface show soft tissue that does not resemble tumor. The tongue is serially sectioned from anterior to posterior revealing two large hard white nodules that are hemorrhagic and ulcerated in appearance. These nodules measure 3.0 x 2.2 cm and 2.0 x 1.9 cm. The second nodule appears to extend down from the two surface nodules that are present on the surface of the tongue. The mass appears to abut the medial margin. Also present in the container is a small piece of detached skeletal muscle tissue measuring 3.3 x 1.4 x 1.0 cm. Representative sections of the tumor and tongue specimen are submitted.

Summary of sections: 2A-2C, mass in relation to posterior margin, 1/1 each; 2D, 2E, mass in relation to inferior margin, 2/1, 1/1; 2F-2H, mass in relation to medial margin, 1/1 each; 2I-2K, mass in relation to superior surface of tongue including surface nodule, 1/1 each; 2L, representative sections of detached muscle fragment, 3/1.

3) SOURCE: Right Neck Level 1

The specimen is received fresh in a container labeled with the patient's name, medical record number and "right neck level 1." The specimen consists of fibroadipose tissue and a candidate lymph node measuring in aggregate 6.3 x 5.5 x 1.4 cm. A thorough lymph node dissection is performed revealing 5 candidate lymph nodes, with the largest measuring 1.6 x 1.0 cm. The lymph nodes are submitted in entirety.

Summary of sections: 3A, 2 candidate lymph nodes, bisected, 4/1; 3B, 3 candidate lymph nodes, 3/1.

4) SOURCE: Tongue Base Lesion

The specimen is received fresh in a container labeled with the patient's name, medical record number and "tongue base lesion." The specimen consists of tissue with a mucosal surface and what appears to be skeletal muscle. The specimen is unoriented and measures 4.0 x 3.5 x 1.3 cm. The entire non-mucosal surface is inked black. The specimen is serially sectioned. Summary of sections: 4A-4F, entire base lesion, M/1 each.

5) SOURCE: Teeth

The specimen is received fresh in a container labeled with the patient's name, medical record number and "teeth for gross only." The specimen consists of 15 teeth that measure in aggregate 6.8 x 4.5 x 0.5 cm. The teeth are a range of molars and incisors and canines. A gross photograph was obtained.

Source: NCI Genomic Data Commons file 152fbaa7-61c6-4330-8b9f-3dfc37d80f70 (TCGA-CR-6493.ABFA2BEF-DD8B-4927-A454-3074935D8B2F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).